MMRF case MMRF_1822 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/72e18d49-073c-4fbe-86bb-716d1360786a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 43.1 years (15,759 days); ISS stage: III; Days to last known disease status: 997 days (2.7 years); Days to last follow up: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 136 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 284 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 746 days (2.0 years); Days to treatment end: 962 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 962 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 5.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.129 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 55.1 mg/dL; Immunoglobulin G 2.59 g/L; Immunoglobulin A 44.8 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 5.9 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.68 mmol/L; Albumin 31 g/L; Total Protein 11.3 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 80 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.685 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 1.11 g/L; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.22 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.
- Day 178 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.672 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.938 mg/dL; Immunoglobulin G 9.91 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 269 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.912 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 9.97 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 9.98 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.71 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 346 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.882 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 9.92 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.76 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 472 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.995 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 9.98 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.58 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 4.79 mmol/L.
- Day 528 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 3 g/L; Immunoglobulin M 0.76 g/L; Hemoglobin 10.6 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.58 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.17 mmol/L.
- Day 710 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.338 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.82 mg/dL; Immunoglobulin G 7.44 g/L; Immunoglobulin A 13.7 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.17 mmol/L.
- Day 833 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.627 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.98 mg/dL; Immunoglobulin G 5.31 g/L; Immunoglobulin A 20.6 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.57 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 868 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.22 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 24.3 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 8.3 g/dL; Glucose 3.85 mmol/L.
- Day 997 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.177 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.7 mg/dL; Immunoglobulin G 4.27 g/L; Immunoglobulin A 29.1 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.72 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 8.4 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -6: Weight: 107 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_1822_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1822_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
